Gene-level copy-number profile of tumor specimen TCGA-RU-A8FL-01A from TCGA case TCGA-RU-A8FL, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 52.0 years (18,975 days).
Specimen TCGA-RU-A8FL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.c11fb399-41f6-42b3-9b3d-89f63f12dead.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RU-A8FL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ed92cb45-eeb0-4ddf-b4c4-558b4d5424e7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 819; copy number 2: 9,417; copy number 3: 23,032; copy number 4: 20,651; copy number 5: 1,834; copy number 6: 1,844; copy number 7: 841; copy number 8: 787; copy number 9: 269; copy number 10: 48; copy number 11: 157; copy number 12: 114; copy number 14: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RU-A8FL-01A-11D-A36W-01): tumor purity 0.72, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,221 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:19,813,749–22,819,575, 22 genes, copy number 7: AC114728.1, AC098862.1, SLIT2, SLIT2-IT1, MIR218-1, PACRGL, KCNIP4, AC097505.1, AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P, ADGRA3, AC098583.1, AC098583.2, GBA3, CDC42P6.
- chr4:51,843,000–59,046,959, 132 genes, copy number 8–11 (within-gene range 6–11) (broad region; genes not listed).
- chr4:59,533,786–60,038,586, 7 genes, copy number 9–14: Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1.
- chr4:69,721,167–76,312,098, 123 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr7:38,257,879–38,311,808, 8 genes, copy number 7: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr8:38,269,704–38,382,272, 1 gene, copy number 10 (within-gene range 1–10): NSD3.
- chr8:38,335,981–46,028,892, 128 genes, copy number 9–10 (broad region; genes not listed).
- chr8:49,817,586–51,809,445, 11 genes, copy number 7 (within-gene range 5–7): AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1.
- chr8:61,057,158–61,501,645, 1 gene, copy number 7 (within-gene range 5–7): CLVS1.
- chr8:61,264,624–64,369,176, 38 genes, copy number 7 (within-gene range 6–7): AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289.
- chr8:67,062,417–88,887,573, 319 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:94,533,628–113,436,939, 300 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:124,192,671–145,066,685, 391 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr13:19,958,670–29,595,688, 213 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr17:27,456,470–30,577,000, 180 genes, copy number 8 (broad region; genes not listed).
- chr22:25,959,074–37,427,445, 346 genes, copy number 7–12 (within-gene range 5–12) (broad region; genes not listed).
- chr22:37,371,684–37,372,858, 1 gene, copy number 7: Z94160.2.

Autosomal genes at a single copy (total copy number 1): 819. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
